Somatic mutation profile of tumor specimen TCGA-DU-6410-01A (aliquot TCGA-DU-6410-01A-11D-1893-08) from TCGA case TCGA-DU-6410, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 56.3 years (20,567 days).
Specimen TCGA-DU-6410-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e84b1e7f-d869-4903-9aba-9c8f2622de6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6410-10A (Blood Derived Normal), aliquot TCGA-DU-6410-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f755cb5-e2aa-4209-b158-6227427a88c1

The open-access MAF lists 40 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 6, Nonsense Mutation 3, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AK9 | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774061625, COSV58137283; called by muse, mutect2, varscan2
- ALB | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as rs141343001, COSV55735894; called by muse, mutect2, varscan2
- ANO5 | c.1012A>T p.S338C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61082063; called by muse, mutect2
- APBB1IP | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63076069; called by muse, mutect2, varscan2
- ARFGEF3 | c.6527T>C p.I2176T | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.084); catalogued as rs746862605, COSV52450181; called by muse, mutect2, varscan2
- ARID1A | c.4624G>T p.E1542* | Nonsense Mutation (SNP) | VAF 44/50 reads (88%) | catalogued as COSV61371858, COSV61383029; called by muse, mutect2, varscan2
- ARMC3 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.219); catalogued as COSV53057187; called by muse, mutect2, varscan2
- CASD1 | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758661663, COSV51970657; called by muse, mutect2, varscan2
- CFTR | c.4121C>T p.A1374V | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50041030; called by muse, mutect2, varscan2
- DDX17 | c.985A>G p.R329G | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53250538; called by muse, mutect2, varscan2
- EDAR | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); catalogued as COSV51499938; called by muse, mutect2, varscan2
- EHMT2 | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV64994571; called by muse, mutect2, varscan2
- ENTPD6 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV61750914, COSV61752272; called by muse, mutect2
- EPHA3 | c.2426G>T p.S809I | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60694432; called by muse, mutect2
- EXTL1 | c.1924T>C p.F642L | Missense Mutation (SNP) | VAF 48/55 reads (87%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV65332179; called by muse, mutect2, varscan2
- FUBP3 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.712); catalogued as COSV60512804; called by muse, mutect2, varscan2
- HHLA2 | c.580T>C p.S194P | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.589); catalogued as COSV63315646; called by muse, mutect2, varscan2
- HK1 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs202028638, COSV100067769, COSV53853045; called by muse, mutect2, varscan2
- INTS3 | c.2959C>T p.R987W | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55162106; called by muse, mutect2, varscan2
- KLHL38 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV58086028; called by muse, mutect2, varscan2
- MARK2 | c.534A>G p.A178= | Splice Region (SNP) | VAF 168/351 reads (48%) | catalogued as COSV59280367; called by muse, mutect2, varscan2
- MATR3 | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1031948008, COSV63075771; called by muse, mutect2, varscan2
- MTO1 | c.1481G>A p.R494Q (on ENST00000370300 / NM_133645.3; = p.R469Q on NM_012123.4) | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs750141214, COSV64773097; called by muse, mutect2
- MYH4 | c.4984G>T p.D1662Y | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55112307; called by muse, mutect2, varscan2
- OR4K17 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs574115281, COSV59647353; called by muse, mutect2, varscan2
- PTPRB | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 60/118 reads (51%) | catalogued as rs772938136, COSV54232377; called by muse, mutect2, varscan2
- RBPJ | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 26/28 reads (93%) | catalogued as COSV60748781; called by muse, mutect2, varscan2
- SCYL1 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1322750590, COSV54210513; called by muse, mutect2, varscan2
- UBE4B | c.1499G>A p.G500D (on ENST00000343090 / NM_001105562.3; = p.G371D on NM_006048.5) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.976); catalogued as rs1490043437, COSV53527144; called by muse, mutect2, varscan2
- USP9X | c.4388T>C p.I1463T | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV61066014; called by muse, mutect2, varscan2
- UTP18 | c.1628G>A p.G543D | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868236909, COSV56582252; called by muse, mutect2, varscan2
- IGLV3-25 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, varscan2
- DIP2A | c.1212G>T p.P404= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV59471895; called by muse, mutect2, varscan2
- IGHV3-30 | c.339T>C p.Y113= | Silent (SNP) | VAF 164/1317 reads (12%) | catalogued as rs1389650902; called by muse, mutect2, varscan2
- KRT25 | c.1017G>A p.A339= | Silent (SNP) | VAF 122/286 reads (43%) | catalogued as rs753281617, COSV56443647; called by muse, mutect2, varscan2
- MUC4 | c.2940C>T p.T980= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs533360052, COSV62129628; called by muse, mutect2, varscan2
- USP7 | c.1287G>A p.E429= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as COSV61212916, COSV61214386; called by muse, mutect2, varscan2
- ZNF71 | c.981G>A p.V327= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs768554116, COSV60146444; called by muse, mutect2, varscan2
- MTCL1 | c.2968-3213C>T | Intron (SNP) | VAF 122/261 reads (47%) | catalogued as COSV60403238; called by muse, mutect2, varscan2
